Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4338, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4338-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Patient with right renal mass.

Specimens Submitted:

1: SP: Left kidney and perinephric fat

DIAGNOSIS:

- 1) KIDNEY, LEFT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR'S GREATEST DIAMETER IS 5.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- [REDACTED]
- [REDACTED]
- [REDACTED]

1) The specimen is received fresh, labeled "Left Kidney and Perinephric Fat". It consists of a radical nephrectomy specimen containing attached perirenal fat, weighing in total 700 grams. The specimen is photographed. The entire perirenal adipose tissue is inked in black. The kidney measures 12.5 cm from superior to inferior, 7.5 cm laterally and 5.5 cm from anterior to posterior. The specimen is opened along the ureter and bivalved revealing an encapsulated, subcapsular, multiloculated mass with areas of central necrosis and hemorrhage, measuring 5.5 x 5.5 x 1.3 cm, situated predominantly within the upper pole of the specimen. The pelvis is markedly compressed and the lining of the ureter surface is pink-tan, smooth and unremarkable. The cortex is pink-tan, unremarkable and measures 0.6 cm. The medullary region measures up to 1.2 cm. The mass is serially sectioned. Extension into the black-inked surface is grossly not identified. The remaining renal calyces is grossly unremarkable and pink-tan. Hilar nodes are grossly not identified. A portion of the tumor is given for TPS and EM. Random sections of the specimen are submitted. A photograph is taken.

Summary of Sections:

UM -- clipped ureter margin

HM -- hilar vessel margin vein artery

UU -- random sections of the ureter requested to be embedded on edge

PDM -- posterior black-inked capsule closest to the encapsulated tumor mass

TPUP -- random sections of the tumor at the posterior aspect

TPP -- tumor at the posterior aspect with random sections of the pelvis

ADM -- anterior deep margin closest to the encapsulated tumor mass

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

TAUP – random sections of the tumor at the anterior aspect upper pole
TAP – tumor at the anterior aspect with random sections of the pelvis
PEL – random sections of pelvis
UP – random sections of upper pole
LP – random sections of lower pole
UPF – random sections of upper pole fat
H – hilar fat

Summary of Sections:

Part 1: SP: Left kidney and perinephric fat

Block	Sect. Site	PCs
2	ADM	2
1	HF	1
1	HM	10
1	LP	2
1	PDM	1
1	PEL	1
1	TAP	1
2	TAUP	2
1	TPP	1
3	TPUP	3
1	UM	1
1	UP	2
1	UPF	1
1	UU	1

Source: NCI Genomic Data Commons file a19d0810-397d-41c6-86b3-fd39b46484de (TCGA-BP-4338.6A5E8345-4EC8-44E4-9D6C-5E0AB42496D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).